Somatic mutation profile of tumor specimen TCGA-KO-8409-01A (aliquot TCGA-KO-8409-01A-11D-2310-10) from TCGA case TCGA-KO-8409, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 69.6 years (25,419 days).
Specimen TCGA-KO-8409-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7913bd80-7f0f-47df-a6ba-fd25db7ea9db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KO-8409-11A (Solid Tissue Normal), aliquot TCGA-KO-8409-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0555be67-22db-45ad-96e0-134c293bda3d

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 10, Silent 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN4 | c.2224A>G p.T742A | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV99400313; called by muse, mutect2, varscan2
- ANTXR2 | c.794C>T p.T265M | Missense Mutation (SNP) | VAF 30/424 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs529468896, COSV99786611; called by muse, mutect2
- C19orf18 | c.446A>C p.D149A | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV100071834; called by muse, mutect2
- CAP2 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs759083931, COSV57734949; called by muse, mutect2, varscan2
- GTF3C2 | c.2459A>G p.E820G | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99272872; called by muse, mutect2, varscan2
- MYF6 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV57351142; called by muse, mutect2, varscan2
- OR2W1 | c.683C>T p.T228M | Missense Mutation (SNP) | VAF 151/190 reads (79%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs774114077, COSV65851453; called by mutect2, varscan2
- PDHA2 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs754242583, COSV54780630; called by muse, mutect2, varscan2
- PPP1R13B | c.2839G>A p.V947M | Missense Mutation (SNP) | VAF 113/229 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567080467, COSV99159555; called by muse, mutect2, varscan2
- TAS2R50 | c.52G>T p.V18F | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.261); catalogued as rs750911685, COSV101114985; called by muse, mutect2
- ANO5 | c.2004G>A p.G668= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as CD134530, COSV100201933; called by muse, mutect2
- EARS2 | c.822G>T p.L274= | Silent (SNP) | VAF 71/145 reads (49%) | catalogued as COSV101492172; called by muse, mutect2, varscan2
- GPR158 | c.2760C>G p.T920= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs369998736; called by muse, mutect2, varscan2
- KIF17 | c.1548G>A p.Q516= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99929215; called by muse, mutect2
- SLC20A2 | c.1302G>A p.S434= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs1451201991, COSV60603555; called by muse, mutect2
- TMEM120A | c.414C>G p.L138= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as COSV100115644; called by muse, mutect2, varscan2
- TSC22D2 | c.268C>T p.L90= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as COSV100721232; called by muse, mutect2, varscan2
